Gene-level copy-number profile of tumor specimen ALCH-B01L-TTP1-A from ALCHEMIST case ALCH-B01L, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.4 years (24,241 days).
Specimen ALCH-B01L-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file aef29738-be48-46c7-8fba-6a0f723fb4b7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B01L-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/a9352106-3b07-4827-8919-1b3646d503a4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 2,069; copy number 2: 54,867; copy number 3: 1,258; copy number 4: 179; copy number 5: 6; copy number 6: 3; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:26,457,203–26,558,756, 1 gene: OTOF.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr13:112,197,350–112,331,225, 3 genes: LINC01070, LINC01043, LINC01044.
- chr16:10,718,633–10,725,296, 8 genes: MTCYBP33, MTND6P33, MTND5P33, MTND4P34, MTND4LP24, MTND3P13, MTCO3P24, MTATP6P24.
- chr17:79,074,824–79,088,599, 1 gene: ENGASE.
- chr17:79,132,722–79,136,402, 1 gene (within-gene range 0–2): AC021534.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:62,602,218–62,615,116, 3 genes, copy number 5: EML3, AP001458.1, ROM1.
- chr14:18,333,726–18,412,264, 2 genes, copy number 5–10: CR383658.1, CR383658.2.
- chr21:10,640,028–13,016,692, 3 genes, copy number 6: AF254982.1, IGHV1OR21-1, AP001464.1.
- chr21:13,095,305–13,120,807, 2 genes, copy number 5: ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 2,069. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
